Somatic mutation profile of tumor specimen ALCH-B4XG-TTP1-A (aliquot ALCH-B4XG-TTP1-A-2-0-D-A81V-36) from ALCHEMIST case ALCH-B4XG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,641 days).
Specimen ALCH-B4XG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04dba2a5-8ffa-41c3-8292-160ee8b66132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XG-NB1-A (Blood Derived Normal), aliquot ALCH-B4XG-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/720da6af-c38a-431e-8ed7-56236bd5d577

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 6, Intron 5, Nonsense Mutation 2, Splice Region 1, In Frame Del 1, Splice Site 1, 3'UTR 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 48/326 reads (15%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99536582; called by muse, varscan2
- ANKRD30A | c.425C>A p.A142D (on ENST00000611781; = p.A86D on NM_052997.2) | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64608816; called by muse, mutect2
- CFHR4 | c.506A>G p.D169G (on ENST00000367416 / NM_001201551.2; = p.D170G on NM_001201550.3) | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99259966; called by muse, mutect2, varscan2
- ERICH3 | c.4001G>A p.G1334E | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV100443693; called by muse, mutect2, varscan2
- FAM170B | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV61253264; called by muse, mutect2, varscan2
- MRTFB | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371187, COSV57959636; called by muse, mutect2
- OR6F1 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs761171958, COSV57467703; called by muse, mutect2
- OTOG | c.6602G>A p.S2201N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs893396157; called by muse, mutect2, varscan2
- POLG | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | catalogued as rs538976075; called by muse, mutect2
- RHOBTB2 | c.95G>C p.C32S | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99311151; called by muse, mutect2, varscan2
- TBX22 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs1351169817; called by muse, mutect2, varscan2
- ZBTB41 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100963481; called by muse, mutect2
- A2M | c.3351+1G>T p.X1117_splice | Splice Site (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- BMS1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRAF | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- C1QB | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); called by mutect2, varscan2
- CACYBP | c.466A>C p.K156Q | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CARTPT | c.263G>A p.C88Y | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH9 | c.1254-7C>T | Splice Region (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- CSTF1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAAF6 | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- DSG3 | c.2879T>C p.I960T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- EFCAB10 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.325); called by muse, mutect2
- GRIK2 | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP1B | c.5515C>T p.Q1839* | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- MMP8 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- MUC2 | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.16); called by muse, mutect2
- OR1L4 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2
- PCDH11Y | c.620A>T p.N207I (on ENST00000400457 / NM_032973.2; = p.N196I on NM_032971.3) | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PIK3CG | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- PLXDC2 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2
- PNPLA3 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- PTGS2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.086); called by muse, mutect2
- SCN7A | c.3012C>G p.D1004E | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SEPHS2 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TEX36 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- ZNF469 | c.11536C>A p.P3846T (on ENST00000437464; = p.P3874T on NM_001367624.2) | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); called by muse, mutect2
- CEP152 | c.2634A>C p.A878= | Silent (SNP) | VAF 16/472 reads (3%) | called by muse, mutect2
- OGFOD2 | c.666C>T p.V222= (on ENST00000228922 / NM_001304833.1; = p.V162= on NM_024623.3) | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs1441288676; called by muse, mutect2, varscan2
- SELE | c.1122G>A p.E374= | Silent (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- SERPINA3 | c.894G>A p.R298= | Silent (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- TMEM268 | c.993C>T p.I331= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ZNF407 | c.4851G>A p.K1617= | Silent (SNP) | VAF 13/254 reads (5%) | catalogued as COSV55262710; called by muse, mutect2
- AL353804.7 | chrX:73852183 C>T | 3'Flank (SNP) | VAF 6/40 reads (15%) | catalogued as rs1470057151; called by mutect2, varscan2
- ARMCX4 | c.1039-3050T>C | Intron (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- CEP57 | c.886-31A>G | Intron (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- MBOAT2 | c.1185+279G>A | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- RPS28 | c.-10C>T | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs764968275; called by muse, mutect2, varscan2
- SCML4 | c.682+4833C>T | Intron (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- SPRYD4 | c.*6357A>C | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ZMYND11 | c.117-11931A>G | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
